Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3611, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3611-01A (Primary Tumor).

Diagnosis:

Rectosigmoid colon with a carcinoma evidently of the colorectal junction extending to a maximum of 2.5 cm within the resection margin with a maximum diameter of 3.5 cm, characterized histologically as a moderately differentiated colorectal adenocarcinoma. Invasive tumor spread within all parietal layers of the intestine as far as the adjacent mesocolic or periproctic fatty tissue.

Colon shows a tubulovillous adenoma of the colon mucosa with a diameter of 3 cm, epithelial dysplasia that is severe in parts (synonym: high-grade intraepithelial neoplasia) and also adenoma of the tubular mucosa with a diameter of 0.8 cm and epithelial dysplasia that is severe in parts (synonym: high-grade intraepithelial neoplasia).

Oral and aboral resection margins tumor-free.

Ten regional lymph nodes tumor-free with non-characteristic reactive lesions .

Tumor stage therefore pT3 pN0 (0/19) L0 V0; G2 R0.

Source: NCI Genomic Data Commons file bc1c4ed7-1425-4bb8-84ba-20e33910e217 (TCGA-AG-3611.C6E6D344-0365-4406-8FF9-8A75C14FF974.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).